Somatic mutation profile of tumor specimen ALCH-AEPG-TTP1-A (aliquot ALCH-AEPG-TTP1-A-2-0-D-A673-36) from ALCHEMIST case ALCH-AEPG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.9 years (24,451 days).
Specimen ALCH-AEPG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3091645-e0aa-4256-9284-9033f18a4b38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEPG-NB1-A (Blood Derived Normal), aliquot ALCH-AEPG-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad238c1-cba5-4b4a-8257-20ec236ba36b

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 2, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 68/488 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- C8B | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV64777537; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs754135731; called by mutect2, varscan2*
- NEB | c.2454G>T p.K818N | Missense Mutation (SNP) | VAF 23/453 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50808203; called by muse, mutect2
- NRG2 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1300530953, COSV56837260; called by muse, mutect2
- CCDC88B | c.2085G>T p.W695C | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.24); called by muse, mutect2
- CDH16 | c.1903C>A p.L635I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CPS1 | c.2531C>G p.S844C | Missense Mutation (SNP) | VAF 22/671 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2
- GPR1 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2
- HAS2 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NUP35 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RTL9 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SCNN1D | c.536C>G p.P179R (on ENST00000338555; = p.P343R on NM_001130413.4) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTLL5 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2
- ZC3H12B | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- CNTN3 | c.1098A>C p.I366= | Silent (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- CD55 | c.1081+1080C>G | Intron (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- PPP3CB | c.85+20C>T | Intron (SNP) | VAF 19/129 reads (15%) | catalogued as rs1564575015; called by muse, mutect2, varscan2
